CCDI case PBCHNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bff6c3d7-23ca-42e9-b8e3-1205f97032ac

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 15.8 years (5,782 days).

Biospecimens (3 samples)
- Sample 0DSG1W: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSG22: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSG2J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
